Gene-level copy-number profile of tumor specimen C3L-01155-01 (profiled together with C3L-01155-02) from CPTAC case C3L-01155, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,461 days).
Specimen C3L-01155-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2f31188-5a40-47fa-b5bd-a6354193fcda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01155-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/669a2e45-16f1-43f4-933e-6ad17b320bc9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 10; copy number 2: 6,083; copy number 3: 839; copy number 4: 40,270; copy number 5: 1,053; copy number 6: 10,398; copy number 7: 54; copy number 8: 32; copy number 12: 4; copy number 15: 1; copy number 17: 6; copy number 22: 10; copy number 23: 38; copy number 24: 13; copy number 25: 5; copy number 27: 23; copy number 32: 2; copy number 81: 1; copy number 89: 42; copy number 90: 2; copy number 162: 1; copy number 175: 4; copy number 185: 5; copy number 200: 2; copy number 267: 5.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 164 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:987,180–1,112,063, 5 genes, copy number 22: AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635.
- chr5:41,585,882–41,895,599, 5 genes, copy number 22: AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1.
- chr5:43,874,367–43,886,628, 1 gene, copy number 23: AC104119.1.
- chr5:44,300,247–44,658,569, 3 genes, copy number 24–25: FGF10, FGF10-AS1, LINC02224.
- chr7:52,165,235–53,036,925, 5 genes, copy number 15–90: AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12.
- chr7:54,330,670–55,862,755, 37 genes, copy number 81–267: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:55,887,277–56,365,270, 21 genes, copy number 89 (within-gene range 4–89): AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8.
- chr7:65,773,620–65,814,775, 2 genes, copy number 32: GTF2IP5, RNU6-912P.
- chr19:5,158,495–5,691,875, 12 genes, copy number 24 (within-gene range 4–24): PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L.
- chr19:8,778,665–9,095,669, 9 genes, copy number 23–25: AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2, OR1M4P, OR1M1.
- chr19:55,475,983–55,988,629, 31 genes, copy number 23: AC008735.3, ZNF628, NAT14, SSC5D, SBK2, SBK3, ZNF579, FIZ1, ZNF524, ZNF865, AC008735.4, ZNF784, ZNF580, ZNF581, CCDC106, U2AF2, AC008735.2, AC008735.1, EPN1, AC010525.1, AC010525.2, AC008749.1, NLRP9, RN7SKP109, RFPL4A, RFPL4AL1, RFPL4AP1, NLRP11, NLRP4, NLRP13, NLRP8.
- chr19:57,681,969–57,753,575, 4 genes, copy number 12 (within-gene range 7–12): ZNF551, AC003006.1, ZNF154, ZNF671.
- chr19:58,034,025–58,118,427, 6 genes, copy number 17: ZSCAN1, LETM1P2, HNRNPDLP4, ZNF135, RN7SL526P, ZSCAN18.
- chr19:58,228,594–58,397,079, 23 genes, copy number 27: ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
